Somatic mutation profile of tumor specimen TCGA-V4-A9EC-01A (aliquot TCGA-V4-A9EC-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EC, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.7 years (27,655 days).
Specimen TCGA-V4-A9EC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e3b3273-088e-420f-86d8-1f807c656001.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EC-10A (Blood Derived Normal), aliquot TCGA-V4-A9EC-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3cb6d11-995f-47ad-8736-a78d4381c9f8

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 25/50 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309275, COSV63309367; called by muse, mutect2, varscan2
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 50/101 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KLHL31 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs893752130; called by muse, mutect2, varscan2
- RPS6KC1 | c.2425G>T p.V809L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1177225810; called by muse, mutect2, varscan2
- SETX | c.1791C>G p.F597L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1338284039; called by muse, mutect2, varscan2
- TNFRSF8 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141205943; called by muse, mutect2
- TYRP1 | c.411_415del p.S137Rfs*42 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as rs769074792; called by mutect2, pindel
- COL4A2 | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- EP300 | c.5885T>C p.M1962T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FANCL | c.1015T>C p.Y339H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HK1 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- LRRC49 | c.260A>C p.E87A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NDN | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RENBP | c.802del p.R268Vfs*15 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- SF3B1 | c.1987A>C p.T663P | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIM2 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SLC39A7 | c.186dup p.G63Wfs*24 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- KRTAP4-4 | c.159C>T p.T53= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101180521; called by muse, mutect2, varscan2
- PNPLA7 | c.2424A>G p.T808= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- RYR2 | c.6321G>T p.T2107= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100772088, COSV63684440; called by muse, mutect2, varscan2
- SLC27A6 | c.369C>T p.F123= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs758990702, COSV99322969; called by muse, mutect2, varscan2
